CCDI case PBBXBK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/416bfcb3-6531-41d3-a4a2-e64ba4b0f4ac

Demographics
Sex at birth: male; Race: american indian or alaska native; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.3 years (3,406 days).

Biospecimens (3 samples)
- Sample 0DJIKW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJIL7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJILS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
